Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8245, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8245-01A (Primary Tumor).

[REDACTED]

Stomach, total gastrectomy:

Advanced gastric carcinoma

(Muc2(+/-)/Muc5AC(-)/Muc6(-)/CD10(+)/cERB2(-), I type)

1. Location : upper third, Center at upper body, posterior wall
2. Gross type : Borrmann type 2
3. Histologic type : papillary adenocarcinoma (70% of tumor mass)
>>poorly differentiated-non solid (por2)
4. Histologic type by Lauren : intestinal
5. Growth pattern: mixed expanding and infiltrative growth pattern
6. Size : 6.2×4.7×1.7 cm
7. Depth of invasion : invades subserosa (pT3)
8. Resection margin: free from carcinoma
- safety margin: distal 12.1 cm, proximal 1.2 cm
9. Lymph node metastasis : no metastasis in all 60 regional lymph nodes (pN0)
(lesser curvature 0/28, greater curvature 0/32)
10. Lymphatic invasion : not identified
11. Venous invasion : not identified
12. Perineural invasion : present, moderate
13. Associated findings
1) foveolar hyperplasia with pit dysplasia

Immunohistochemistry : CD10, MUC2, MUC5ac, MUC6, C-erb B2

Source: NCI Genomic Data Commons file 3a280902-4556-4eef-9ee1-704cee715f92 (TCGA-HU-8245.A84511FE-64E2-402C-AD6C-AEBF5780C717.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).